Somatic mutation profile of tumor specimen 0DT20V from CCDI case PBCIMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.2 years (3,736 days).
Specimen 0DT20V: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fd06abb-c1b1-4f2c-8661-983cda92313a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT20J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f0d090f-43af-4bbe-a00f-1f4dc3478f56

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP13 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 34/610 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs749878900; called by muse, mutect2
- ANKRD30B | c.1039T>A p.S347T | Missense Mutation (SNP) | VAF 34/912 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); called by muse, mutect2
- WDFY1 | c.571G>T p.V191F | Missense Mutation (SNP) | VAF 203/557 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- KLHDC10 | c.54C>T p.A18= | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as rs940236622; called by muse, mutect2
- PCDHGC5 | c.177G>T p.L59= | Silent (SNP) | VAF 20/634 reads (3%) | called by muse, mutect2
